Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A67M, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A67M-01A (Primary Tumor).

[page 1 of 5]
MRN
Name
Encounter Number
Gender M
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

Results

Final

Source of Specimen

- A. TISSUE ANTERIOR TO PROSTATE-
- B. LEFT PELVIC LYMPH NODES-
- C. RIGHT PELVIC LYMPH NODES-
- D. HERNIA SAC-
- E. PROSTATE GLAND SEMINAL VESICLES AND VAS DEFERENS-

FINAL DIAGNOSIS:

- A. TISSUE ANTERIOR TO PROSTATE-
ADIPOSE TISSUE, NO TUMOR SEEN.
- B. LEFT PELVIC LYMPH NODES-
LYMPH NODES, NO TUMOR SEEN.
- C. RIGHT PELVIC LYMPH NODES-
LYMPH NODES, NO TUMOR SEEN.
- D. HERNIA SAC-
ADIPOSE TISSUE.
- E. PROSTATE GLAND SEMINAL VESICLES AND VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE WITH EXTENSION INTO EXTRAPROSTATIC
SOFT TISSUE.

TUMOR SITE: RIGHT AND LEFT SIDES.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 40 GRAMS.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 4 + 3 = 7/10.

TNM STAGE: pT3a, pN0, pMX.

Prepared for

Criteria	4/22/13	Yes	No
Diagnostic Discrepancy			

[page 2 of 5]
LYMPHATIC (SMALL VESSEL) INVASION: IS SEEN.

PERINEURAL INVASION: IS PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT MARGINS OF PROSTATE, SOFT TISSUE, URETHRA AND PENIS AND NECK.

Signature

(Case signed)

Case Clinical Information

PROSTATE CANCER UMBILICAL HERNIA

Gross Description

A. Received in formalin labeled with the patient's name and "tissue anterior to prostate" is a 5.0 cm aggregate of tan yellow fatty tissue with no palpable masses identified. The cut surface has a fatty uniform appearance and is grossly unremarkable. The entire specimen is submitted A1-A5.

B. Received in formalin labeled with the patient's name and "left pelvic lymph node" are three nodules of tan fatty tissue grossly consistent with lymphoid tissue, ranging in size from 1.8 cm down to 0.6 cm. The excess fat is trimmed and all three nodules are submitted B1-B3 with one possible lymph node in each cassette.

C.

Received in formalin labeled with the patient's name and "right pelvic lymph nodes" are three nodules of tan fatty tissue grossly consistent with lymphoid tissue, ranging in size from 3.0 cm down to 1.0 cm. The excess fat is trimmed. The cut surface of the largest nodule has a focal hemorrhagic glistening appearance. All three nodes are submitted as follows:

C1-C2=one lymph node that has been bisected; C3, C4=one lymph node each.

D. Received in formalin labeled with the patient's name and "hernia sac" is an irregular fragment of tan-pink glistening fibrofatty tissue measuring 5 x 3 x 1.0 cm maximal thickness. A representative section is submitted in D1.

E. Received in formalin labeled "prostate gland seminal vesicle and vas deferens" is a radical prostatectomy specimen which includes a 40 gram prostate gland with attached seminal vesicles and small segments of vasa deferentia. The gland measures 4 x 3.5 x 3.5 cm and has a shaggy capsule that is disrupted at the

Prepared for:

[page 3 of 5]
bladder margin and the specimen has been previously inked black on the left and blue on the right. The right seminal vesicle measures 3.5 x 1.0 x 1.0 cm. The right vas deferens measures 4.0 cm in length. The left seminal vesicle measures 3.0 x 1.0 x 1.0 cm. The left vas deferens measures 3.0 cm in length. The inferior prostate is sectioned transversely, removed from the rest of the specimen, and then sectioned from anterior to posterior parallel to the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no gross abnormalities. Section code is as follows: the inferior prostate demonstrating apical margin submitted entirely anterior to posterior=E1-E10; bladder margin=E11; complete section of mid gland anterior=E12-E13; posterior aspect=E14-E15; complete sections of upper third of gland, anterior E16-E17, posterior aspect=E18-E19; remainder of posterior gland submitted=E20-E22; right seminal vesicle and vas deferens=E23; left seminal vesicle and vas deferens=E24. Tissue was also taken for research.

Physicians

Procedure

- A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.5
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.4
H&E X1

Prepared for _____

[page 4 of 5]
D. AA ROUTINE H&E X1 BLOCK
H&E X1
E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.4
H&E X1
E. AA ROUTINE H&E X1 BLOCK.5
H&E X1
E. AA ROUTINE H&E X1 BLOCK.6
H&E X1
E. AA ROUTINE H&E X1 BLOCK.7
H&E X1
E. AA ROUTINE H&E X1 BLOCK.8
H&E X1
E. AA ROUTINE H&E X1 BLOCK.9
H&E X1
E. AA ROUTINE H&E X1 BLOCK.10
H&E X1
E. AA ROUTINE H&E X1 BLOCK.11
H&E X1
E. AA ROUTINE H&E X1 BLOCK.12
H&E X1
E. AA ROUTINE H&E X1 BLOCK.13
H&E X1
E. AA ROUTINE H&E X1 BLOCK.14
H&E X1
E. AA ROUTINE H&E X1 BLOCK.15
H&E X1
E. AA ROUTINE H&E X1 BLOCK.16
H&E X1
E. AA ROUTINE H&E X1 BLOCK.17
H&E X1
E. AA ROUTINE H&E X1 BLOCK.18
H&E X1
E. AA ROUTINE H&E X1 BLOCK.19
H&E X1
E. AA ROUTINE H&E X1 BLOCK.20
H&E X1
E. AA ROUTINE H&E X1 BLOCK.21
H&E X1
E. AA ROUTINE H&E X1 BLOCK.22
H&E X1
E. AA ROUTINE H&E X1 BLOCK.23
H&E X1
E. AA ROUTINE H&E X1 BLOCK.24

Prepared for

[page 5 of 5]
H&E X1 A RECUTS

Prepared for

Source: NCI Genomic Data Commons file d71480ad-ebad-4971-8ccf-5314f738a820 (TCGA-J4-A67M.590FEE5C-E5FF-4DB2-8A7E-6502E5B9A56B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).